Somatic mutation profile of tumor specimen TCGA-DJ-A2Q8-01A (aliquot TCGA-DJ-A2Q8-01A-11D-A18F-08) from TCGA case TCGA-DJ-A2Q8, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 47.7 years (17,438 days).
Specimen TCGA-DJ-A2Q8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d25fe2d5-5f93-437d-927b-3adbfd8548dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2Q8-10A (Blood Derived Normal), aliquot TCGA-DJ-A2Q8-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64c3b96b-cc26-4ec7-922c-b97666355f3a

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.2018T>A p.L673* | Nonsense Mutation (SNP) | VAF 11/181 reads (6%) | catalogued as COSV52126089; called by muse, mutect2
- SPTA1 | c.3080C>T p.P1027L | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63754395; called by muse, mutect2
- VCP | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.713); catalogued as COSV62720808; called by muse, mutect2, varscan2
- MYBPC3 | c.750C>T p.S250= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV57028495; called by muse, mutect2, varscan2
